Somatic mutation profile of tumor specimen 0DGBAF from CCDI case PBBTEC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 7.1 years (2,587 days).
Specimen 0DGBAF: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e08da33b-b25e-4f98-8c3c-44e77531bdff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGB94 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89f19c24-8c27-4531-a8ea-52188331957b

The open-access MAF lists 7 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, RNA 2, 5'UTR 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP1R26 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 87/298 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- ZNRF3 | c.988T>C p.C330R (on ENST00000544604 / NM_001206998.2; = p.C230R on NM_032173.3) | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as rs1167537044; called by muse, varscan2
- CTSC | c.318+6725T>G | Intron (SNP) | VAF 12/96 reads (13%) | called by muse, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 12/120 reads (10%) | called by muse, varscan2
- LINC02694 | n.552G>A | RNA (SNP) | VAF 12/116 reads (10%) | catalogued as rs768118261; called by muse, varscan2
- SLC29A1 | c.-336T>C | 5'UTR (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
